Gene-level copy-number profile of tumor specimen BLGSP-71-06-00088-01B from CGCI case BLGSP-71-06-00088, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.0 years (2,209 days).
Specimen BLGSP-71-06-00088-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 18c49419-4bdd-42b8-bcba-13a6db8d84fd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00088-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,269 have no estimate.
https://portal.gdc.cancer.gov/files/1962691e-851c-4c9d-a37a-4604234a2741

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 172; copy number 2: 57,355; copy number 3: 780; copy number 4: 30; copy number 5: 12; copy number 8: 1; copy number 9: 3; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,197,992–149,321,732, 3 genes, copy number 9 (within-gene range 4–9): AC245297.1, AC245297.2, 7SK.
- chr2:87,748,087–87,825,952, 2 genes, copy number 5 (within-gene range 3–5): PLGLB2, RGPD2.
- chr8:7,811,720–7,829,053, 3 genes, copy number 5: DEFB107A, DEFB105A, DEFB106A.
- chr9:64,810,865–64,811,429, 1 gene, copy number 5: BNIP3P4.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:20,901,441–20,901,609, 1 gene, copy number 31: ZNF519P2.
- chr16:32,439,069–32,441,159, 1 gene, copy number 8: PABPC1P13.
- chr16:32,475,051–32,478,250, 1 gene, copy number 5: ABCD1P3.
- chr22:18,833,694–18,834,438, 1 gene, copy number 5: E2F6P1.

Autosomal genes at a single copy (total copy number 1): 172. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
